Surgical pathology report (de-identified scan), TCGA case TCGA-KM-8442, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-8442-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS: Kidney, right, mass, resection: Renal cell carcinoma, chromophobe type, margins of resection are free of tumor.

CLINICAL INFORMATION: [REDACTED] Brief Clinical History: right renal mass [REDACTED]

PROCEDURE: Pre-Operative Diagnosis: renal mass Post-Operative Diagnosis: renal mass Operative Findings: renal mass

SPECIMENS SUBMITTED: 1. KIDNEY, RIGHT, Renal mass

GROSS DESCRIPTION: Received fresh in a container labeled with the patient's name, medical record number, and further specified as "right renal mass". The specimen is a partial nephrectomy with attached fatty tissue measuring 10.5 x 9.3 x 9.0 cm, with a kidney surface measuring 7 x 0.3 cm. The specimen is inked in black, bisected revealing tan-yellow-red cut surface. Approximately 4 x 3 x 2 cm is procured for [REDACTED]. There is also an additional piece of kidney parenchyma with attached suture. This is indicated as superior pole as per surgeon. In Surgical Pathology, the specimen received matches the above description. Photographs are taken, and the specimen was sliced and fixed in formalin, and representative sections are submitted in white cassettes labeled : [REDACTED] for permanent processing. The additional piece of kidney parenchyma measures 5 x 3 x 1.8 cm with a suture attached to the pelvis and ureter. The top part of the parenchyma is inked in blue and the specimen is serially sectioned and entirely submitted in white cassettes labeled : [REDACTED] R for permanent processing.

The procurement was performed by [REDACTED]

Gross description dictated by [REDACTED]

No consultants

[page 2 of 2]
[Redacted]

[Redacted]

[Redacted]

Patient Identification

Source: NCI Genomic Data Commons file b7dc578d-4ae0-4474-ad4e-455bc93cecf9 (TCGA-KM-8442.7B12CA00-9CCE-46BD-8DA0-203FC698D64D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).